Somatic mutation profile of tumor specimen 0DSPLX from CCDI case PBCIIP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.2 years (803 days).
Specimen 0DSPLX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d9f2ceb-4539-4e3a-894b-12da32b53c11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSPM1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af48e047-9112-4343-80c9-03ec236de97c

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRXN1 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 69/360 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as COSV67999619; called by muse, mutect2, varscan2
- OR10G8 | c.384G>A p.P128= | Silent (SNP) | VAF 54/365 reads (15%) | catalogued as rs1331551730, COSV70908394; called by muse, mutect2, varscan2
- CRIP2 | c.138+25C>T | Intron (SNP) | VAF 34/197 reads (17%) | catalogued as COSV61274594; called by muse, mutect2, varscan2
